Somatic mutation profile of tumor specimen TCGA-LK-A4NZ-01A (aliquot TCGA-LK-A4NZ-01A-12D-A34C-32) from TCGA case TCGA-LK-A4NZ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 75.9 years (27,720 days).
Specimen TCGA-LK-A4NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a854d3f-6c00-4b9f-8e39-45f1c99e6c90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4NZ-10A (Blood Derived Normal), aliquot TCGA-LK-A4NZ-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d858ca14-fee9-48c5-94d4-007fdfd3b6d0

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GALT4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs753990904; called by muse, mutect2, varscan2
- BPNT2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs758965196, COSV52907247; called by muse, mutect2, varscan2
- CD274 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV101056102; called by muse, varscan2
- COL6A2 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.235); catalogued as rs367658663; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HMBOX1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763363239, COSV55067536; called by muse, mutect2, varscan2
- MYO10 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371195902; called by muse, mutect2, varscan2
- NF2 | c.431dup p.Y144* | Nonsense Mutation (INS) | VAF 12/46 reads (26%) | catalogued as CI045510, CI983522, COSV58520618; called by mutect2, pindel, varscan2
- PCSK2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52732903; called by muse, mutect2, varscan2
- S1PR3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs546398741; called by muse, mutect2, varscan2
- TTN | c.30168G>T p.R10056S (on ENST00000591111; = p.R9129S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/258 reads (17%) | PolyPhen benign (0.037); catalogued as COSV60370203; called by muse, mutect2, varscan2
- VN1R4 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as rs1193097584, COSV60805008; called by muse, mutect2, varscan2
- ZFHX3 | c.6698C>G p.P2233R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.68); catalogued as rs1174057267; called by muse, mutect2, varscan2
- ABI2 | c.1390A>G p.K464E (on ENST00000295851 / NM_001375719.1; = p.K426E on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ADAT3 | c.165C>G p.D55E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.199); called by mutect2, varscan2
- ARIH1 | c.958T>G p.L320V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.736A>T p.R246* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- JPH1 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP2 | c.8393_8394dup p.I2799Lfs*6 | Frame Shift Ins (INS) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- MYRF | c.425C>T p.S142L (on ENST00000278836 / NM_001127392.3; = p.S133L on NM_013279.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NDST2 | c.974A>T p.E325V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.2567C>A p.T856N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ULBP2 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MARF1 | c.3900C>T p.Y1300= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs1352943687; called by muse, mutect2, varscan2
- MYO7B | c.1035C>T p.D345= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs764043935, COSV67345136, COSV67349655; called by muse, mutect2
- NLRC3 | c.1569G>A p.P523= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs753873843; called by muse, mutect2
- RPUSD3 | c.36C>T p.R12= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SMG5 | c.345G>A p.L115= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- TERT | c.2661G>T p.L887= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs756519152, COSV57208279; called by muse, mutect2, varscan2
